Gene-level copy-number profile of tumor specimen TCGA-EJ-5510-01A from TCGA case TCGA-EJ-5510, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 49.0 years (17,895 days).
Specimen TCGA-EJ-5510-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.78c3c78f-0b4c-4c9f-b92b-ef100329d667.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-5510-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c196c105-dfaf-4ffa-b04c-9f90e3f2a23b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,475; copy number 2: 51,732; copy number 3: 2,613.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-5510-01A-01D-1574-01): tumor purity 0.38, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,089. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
